Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29P, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29P-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Tumour right axilla. "Right axilla" fibrofatty tissue covered with skin ellipse. A large nodular 100 x 100 x 90 in the subcutis 5mm x 2 slice for tumour banking taken.

1. Melanoma - right axillary contents (large metastasis in right pec major. Sent to tumour bank separately stitch at apex of axilla. 2. Node from behind choracobrachialis.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrant:

ICA-0-3

Melanoma, Nos 8720/3

Site: lymph node, Axilla C77.3

W 6/23/11

MACROSCOPIC DESCRIPTION

(E

Three specimens received.

1. "AXILLARY LUMP (RIGHT)". Specimen consists of fibrofatty tissue, with overlying ellipse of skin. The fibrofatty tissue measures 105 x 210 x 95mm with a skin ellipse measuring 230mm x 80mm. Surface of skin shows 7 warty lesions measuring from 7mm to 15mm with a height of 5mm. A large nodule is present in subcutis measuring 100 x 100 x 90mm. On serial sectioning the surface of tumour is pale grey with cystic and solid areas and areas of haemorrhage. Tumour is 1mm away from closest surgical margin.

1A-1E. Representative section of tumour showing relationship with surgical margin.
1F. Representative section of skin.

2. "RIGHT AXILLARY CONTENTS". Specimen consists of a piece of fibrofatty tissue, measuring 150mm x 130 x 30mm. There is a stitch present at one side, which is labelled as stitch at apex of axillary according to the request form. Specimen sequentially bisected starting from stitch side. 15 lymph nodes were identified.

- 2A. Contains lymph node at the site of stitch. Further lymph nodes are embedded serially from proximal to distal.
2B. Four lymph nodes.
2C. One lymph node.
2D. One lymph node.
2E. Two lymph nodes.
2F. One lymph node.
2G. Three lymph nodes.
2H. One lymph node.
2J. One lymph node. Lymph nodes in Block 2D & 2J are bisected.

3. "FROM BEHIND CHORACOBRACHIALIS". Specimen consists of a piece of fibrofatty tissue, containing a lymph node, measuring 20mm across. All embedded in Block 3A.

[page 2 of 2]
HISTOPATHOLOGY REPORT**MICROSCOPIC REPORT**

1. "AXILLARY LUMP (RIGHT)". Sections show an expansible mass composed of pleomorphic malignant cells with prominent nucleoli and central necrosis. Immunohistochemistry for S100, HMB45 and Melan A is positive consistent with metastatic malignant melanoma. A thin rim of lymphoid cells is apparent at the edge in some sections, consistent with origin from a lymph node. No unequivocal extranodal spread is seen in the sections examined.

The tumour is less than 0.2mm from the inked resection margin.

The overlying skin lesion sampled (1F) is a seborrheic keratosis.

2. "RIGHT AXILLARY CONTENTS". None of 14 lymph nodes show evidence of metastatic melanoma. Increased numbers of pigmented histiocytes are noted in sinuses and an incidental hemangioma is noted in one node (2D).

3. "FROM BEHIND CHORACOBRACHIALIS". Sections of lymph node show numerous pigmented sinus histiocytes. No diagnostic tumour cells are identified on H&E or immunohistochemistry for S100, HMB45 and MelanA.

SUMMARY**1. Right axillary mass**

- metastatic melanoma.

/

2. Right axillary contents

- no evidence of malignancy in 14 nodes.

/

3. Lymph node from behind right choracobrachialis

- no evidence of malignancy.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file ce26b98d-1d92-4f19-a0aa-abdb78b38652 (TCGA-EE-A29P.CD9AA141-2F94-4C67-9D53-C43C2A316BDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).